Somatic mutation profile of tumor specimen TCGA-D3-A1Q7-06A (aliquot TCGA-D3-A1Q7-06A-11D-A19A-08) from TCGA case TCGA-D3-A1Q7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 44.4 years (16,214 days).
Specimen TCGA-D3-A1Q7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad66020f-18be-4ae5-8cb4-421df42751a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1Q7-10A (Blood Derived Normal), aliquot TCGA-D3-A1Q7-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/535d8ce3-f002-4125-a1ed-863e9889bf28

The open-access MAF lists 113 somatic variants for this specimen: 68 protein-altering or splice-affecting, 43 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 43, Nonsense Mutation 4, Splice Site 3, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RB1 | c.1961-2A>C p.X654_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | hotspot (GDC flag); catalogued as CS040294, COSV57297055, COSV57312910; called by muse, mutect2, varscan2
- ACACB | c.3596C>T p.S1199L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs763388361, COSV58130479; called by muse, mutect2, varscan2
- ADAM33 | c.2252G>A p.G751D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.819); catalogued as rs1429772298, COSV62935401; called by muse, mutect2
- ADAM9 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV65960878; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3581G>A p.G1194E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.966); catalogued as rs1407507280, COSV65893649; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs267601483, COSV58441747; called by muse, mutect2, varscan2
- ADGRA1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66926096; called by muse, mutect2, varscan2
- ADGRG4 | c.5721G>A p.M1907I | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV54959784; called by muse, mutect2, varscan2
- ARMC12 | c.422G>A p.R141K (on ENST00000373866 / NM_001286574.2; = p.R168K on NM_145028.5) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.43); catalogued as COSV55360505; called by muse, mutect2, varscan2
- BDKRB1 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV53706532; called by muse, mutect2, varscan2
- BRWD3 | c.4570T>C p.F1524L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV64749807; called by muse, mutect2, varscan2
- BSN | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56521225; called by muse, mutect2, varscan2
- BSN | c.6802C>T p.P2268S | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV56515788; called by muse, mutect2, varscan2
- C8A | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs765241899, COSV63484968; called by muse, mutect2, varscan2
- CCNB3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV52072406; called by muse, mutect2, varscan2
- CHGB | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV66760854; called by muse, mutect2
- CUL7 | c.2697T>A p.S899R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54818792; called by muse, mutect2, varscan2
- CXorf58 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs775086373, COSV64858461; called by muse, mutect2, varscan2
- CYP20A1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.076); catalogued as rs754972297, COSV61909785, COSV61910402; called by muse, mutect2, varscan2
- DDIAS | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV61272468; called by muse, mutect2, varscan2
- DNM3 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62457191; called by muse, mutect2, varscan2
- DRICH1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV58504140; called by muse, mutect2, varscan2
- EPHB2 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65863497; called by muse, mutect2
- EPHB6 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV67419157; called by muse, mutect2, varscan2
- FAT1 | c.3596C>T p.T1199M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769544525, COSV71674780; called by muse, mutect2, varscan2
- GRIP2 | c.899A>C p.D300A (on ENST00000619221; = p.D203A on NM_001080423.4) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV56122387; called by muse, mutect2
- GTF2A2 | c.73T>A p.S25T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV51115087; called by muse, mutect2
- HSPA5 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV61029459; called by mutect2, varscan2
- HTR3B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs772570898, COSV52744677; called by muse, mutect2, varscan2
- KCNC1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56395355; called by muse, mutect2, varscan2
- KLHL20 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV52943069; called by muse, mutect2
- LAMA5 | c.4813C>T p.P1605S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV53363102; called by muse, mutect2, varscan2
- LILRB4 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV54406380, COSV99553375; called by muse, varscan2
- MEP1A | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV57922995; called by muse, mutect2, varscan2
- MPP1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV65728407; called by muse, mutect2, varscan2
- MSI1 | c.652+1G>A p.X218_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | catalogued as COSV57456745; called by muse, mutect2
- MYH8 | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV67967463; called by muse, mutect2, varscan2
- MYO1F | c.2981G>A p.R994Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs764273527, COSV57795585, COSV57795660; called by muse, mutect2, varscan2
- NAT2 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.81); catalogued as COSV54061345; called by muse, mutect2, varscan2
- NGF | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772557857, COSV101049373, COSV65686846; called by muse, mutect2, varscan2
- NKD2 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780350408, COSV56890598; called by muse, mutect2, varscan2
- NRXN3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs941487848, COSV100199777, COSV100208182; called by muse, mutect2, varscan2
- NWD1 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60344836; called by muse, mutect2, varscan2
- OR2M3 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs267598500, COSV71759081; called by muse, mutect2, varscan2
- PCDHA10 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.046); catalogued as COSV56516308; called by muse, mutect2, varscan2
- PCLO | c.13685C>T p.P4562L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as rs267601585, COSV61626000; called by muse, mutect2, varscan2
- PHACTR3 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs1202354620, COSV100733128; called by muse, mutect2, varscan2
- PTHLH | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs932755478, COSV52367331, COSV52369774; called by muse, mutect2, varscan2
- PTPRD | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61957475; called by muse, mutect2, varscan2
- RAG2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV57558259; called by muse, mutect2, varscan2
- RB1 | c.540-1G>A p.X180_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as CS930863, COSV57312904; called by muse, mutect2
- RFX6 | c.2663G>A p.G888E | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs868134471, COSV60585805; called by muse, mutect2, varscan2
- RSPO3 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV63151561; called by muse, mutect2, varscan2
- SALL1 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51759568; called by muse, mutect2, varscan2
- SEC23B | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111758941, COSV52718128; called by muse, mutect2, varscan2
- SLCO6A1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65811703; called by muse, mutect2, varscan2
- SNCAIP | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV54413561; called by muse, mutect2, varscan2
- STRC | c.4489G>A p.G1497R | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV55852863; called by muse, mutect2, varscan2
- SZT2 | c.4871C>T p.P1624L (on ENST00000634258 / NM_001365999.1; = p.P1567L on NM_015284.4) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65171061; called by muse, mutect2, varscan2
- TKT | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs782486373, COSV56245862; called by muse, mutect2, varscan2
- TRPM1 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 68/371 reads (18%) | catalogued as rs1412079218, COSV56636879; called by muse, mutect2, varscan2
- TSSK1B | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV66815506; called by muse, mutect2, varscan2
- TTI1 | c.2704C>T p.Q902* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV65062031; called by muse, mutect2, varscan2
- VEGFC | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.039); catalogued as rs761889542, COSV54599087; called by muse, mutect2, varscan2
- ZFHX3 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs140908169; called by muse, mutect2, varscan2
- ZFHX3 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1373732636, COSV99214392; called by muse, mutect2, varscan2
- IGLV3-19 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ABCA4 | c.18G>A p.Q6= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV64674631; called by muse, mutect2, varscan2
- ACAN | c.4878C>T p.P1626= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as rs754969277, COSV61363085; called by muse, mutect2, varscan2
- ADGRB1 | c.3906C>T p.F1302= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs768079821, COSV60098759; called by muse, mutect2, varscan2
- ADGRE2 | c.1065C>T p.F355= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV59694271, COSV59694412; called by muse, mutect2, varscan2
- CACNA1E | c.1770G>A p.R590= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV62401910; called by muse, mutect2, varscan2
- CBLN2 | c.243C>T p.S81= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV54051727; called by muse, mutect2, varscan2
- CFTR | c.630C>T p.L210= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as COSV50064811; called by muse, mutect2, varscan2
- CHD4 | c.1878C>T p.H626= (on ENST00000357008 / NM_001363606.2; = p.H639= on NM_001273.5) | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV58904183; called by muse, mutect2, varscan2
- CHRNA9 | c.1278G>A p.R426= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV59574896; called by muse, mutect2
- CNNM4 | c.1846C>T p.L616= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs1292927073, COSV65660543; called by muse, mutect2, varscan2
- CORIN | c.3078C>T p.F1026= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs540619947, COSV56693708; called by muse, mutect2, varscan2
- DOCK2 | c.3459G>A p.L1153= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV56966583; called by muse, mutect2
- DSC3 | c.819G>A p.P273= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs374250811; called by muse, mutect2, varscan2
- EIF2AK4 | c.3270C>T p.P1090= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs758365298, COSV55469924; called by muse, mutect2, varscan2
- GRIN2A | c.2265C>T p.I755= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs867861376, COSV58040489; called by muse, mutect2, varscan2
- GTSE1 | c.912C>T p.I304= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV71889319; called by muse, mutect2, varscan2
- H2BC1 | c.310C>T p.L104= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs372526588; called by muse, mutect2, varscan2
- HAL | c.1014T>G p.L338= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV54118581; called by muse, mutect2, varscan2
- HDAC9 | c.2811G>A p.T937= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs760139178, COSV67766135; called by muse, mutect2, varscan2
- HSPA2 | c.930C>T p.A310= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs757222948, COSV55970337; called by muse, mutect2, varscan2
- ITGB5 | c.1002C>T p.I334= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV56150244; called by muse, mutect2, varscan2
- KIR2DL3 | c.354G>A p.L118= | Silent (SNP) | VAF 60/622 reads (10%) | catalogued as rs1231426201; called by muse, mutect2
- MAGEA3 | c.750C>T p.F250= | Silent (SNP) | VAF 39/181 reads (22%) | catalogued as rs782271747, COSV64756293; called by muse, mutect2, varscan2
- MAP3K6 | c.2037C>T p.I679= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV62888977; called by muse, mutect2, varscan2
- MEP1A | c.1332C>T p.V444= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs761242918, COSV100043058; called by muse, mutect2, varscan2
- NEURL4 | c.2530C>T p.L844= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV59751005; called by muse, mutect2, varscan2
- NOVA1 | c.639G>A p.G213= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV57480155; called by muse, mutect2, varscan2
- OR13C3 | c.945G>A p.G315= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV66165973; called by muse, mutect2, varscan2
- OR4A5 | c.759C>T p.F253= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV60521402, COSV60521592; called by muse, mutect2, varscan2
- PACS1 | c.1020G>A p.R340= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs985741302, COSV57698367; called by muse, mutect2, varscan2
- PARP14 | c.3102C>T p.S1034= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1349708101, COSV71734264; called by muse, varscan2
- PCDHB3 | c.2322C>T p.F774= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs782811619, COSV50566253, COSV50575056; called by muse, mutect2, varscan2
- PDPR | c.2313C>A p.I771= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV55353495; called by muse, mutect2
- PER1 | c.582C>T p.S194= | Silent (SNP) | VAF 47/264 reads (18%) | catalogued as rs766052187, COSV57920433; called by muse, mutect2, varscan2
- PEX14 | c.765C>A p.A255= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs755259929, COSV63061952; called by muse, mutect2, varscan2
- PHACTR3 | c.1224G>A p.R408= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as COSV63029954; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1368C>T p.L456= (on ENST00000352766; = p.L377= on NM_181334.5) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs139004299, COSV61234670; called by muse, mutect2, varscan2
- SEZ6L2 | c.570G>A p.G190= (on ENST00000308713 / NM_001114099.3; = p.G120= on NM_012410.4) | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs755589385, COSV58098267, COSV58100714; called by muse, mutect2, varscan2
- SLC38A8 | c.1158C>T p.F386= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV55307660; called by muse, mutect2, varscan2
- SNX30 | c.606C>T p.F202= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV65292914; called by muse, mutect2, varscan2
- SQLE | c.384C>T p.I128= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs549685736, COSV56281524; called by muse, mutect2, varscan2
- TLE1 | c.741C>T p.N247= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV64690862; called by muse, mutect2, varscan2
- TSC2 | c.1284C>T p.S428= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1325874616, COSV54769062; called by muse, mutect2, varscan2
- LINC01559 | n.466G>A | RNA (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- PISD | c.322-1826C>T | Intron (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99837378; called by muse, mutect2, varscan2
